Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3818, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3818-01A (Primary Tumor).

Tumor entity

This concerns a moderately differentiated, invasive colic adenocarcinoma, partly of the type of an extracellular mucus-forming carcinoma with penetration of all wall layers (pT3, L0, V0), with free resection margins and concomitant chronic recurrent appendicitis. There are also free lymph nodes.

pN0

Source: NCI Genomic Data Commons file 72d91ab2-4250-45e7-bf5d-c488628940c4 (TCGA-AA-3818.F5BD12B0-E886-4DA5-B7B6-B264D4C61439.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).